Somatic mutation profile of tumor specimen TARGET-40-NAAGJS-01A (aliquot TARGET-40-NAAGJS-01A-01D) from TARGET case TARGET-40-NAAGJS, project TARGET-OS (Osteosarcoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Osteosarcoma, NOS; Tissue or organ of origin: Long bones of lower limb and associated joints; Age at diagnosis: 10.5 years (3,833 days).
Specimen TARGET-40-NAAGJS-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 7089d196-5a0b-4216-a447-0e5c76fd734d.targeted_sequencing.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-40-NAAGJS-10A (Blood Derived Normal), aliquot TARGET-40-NAAGJS-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/821765d3-a03a-443f-9ce2-8faf0f2294fc

The open-access MAF lists 6 somatic variants for this specimen: 4 protein-altering or splice-affecting, 2 silent.
By variant classification: Missense Mutation 4, Silent 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CACNA1G | c.337C>T p.R113C | Missense Mutation (SNP) | VAF 88/93 reads (95%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); catalogued as rs1264202646; called by muse, mutect2, varscan2
- DNAH9 | c.1663G>C p.E555Q | Missense Mutation (SNP) | VAF 28/220 reads (13%) | SIFT tolerated (0.11); PolyPhen benign (0.257); catalogued as COSV52357151; called by muse, mutect2, varscan2
- HERC1 | c.2813C>A p.T938N | Missense Mutation (SNP) | VAF 17/65 reads (26%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.987); catalogued as rs139697771; called by muse, mutect2, varscan2
- CDH4 | c.638A>C p.D213A | Missense Mutation (SNP) | VAF 45/183 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.858); called by muse, mutect2, varscan2
- CSMD3 | c.7407A>T p.I2469= (on ENST00000297405 / NM_001363185.1; = p.I2365= on NM_052900.3) | Silent (SNP) | VAF 23/228 reads (10%) | called by muse, mutect2, varscan2
- SYNE1 | c.6015A>T p.R2005= (on ENST00000367255 / NM_182961.4; = p.R2012= on NM_033071.3) | Silent (SNP) | VAF 23/72 reads (32%) | called by muse, mutect2, varscan2
